Somatic mutation profile of tumor specimen PCProject_0336_T1_WES (aliquot PCProject_0336_T1_WES_1) from CMI case PCProject_0336, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.5 years (23,559 days).
Specimen PCProject_0336_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91eb8459-3e1c-4139-ac9f-8193aa818354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0336_SALIVA (DNA), aliquot PCProject_0336_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/140b0601-e3aa-428b-badf-8dc99597f6e2

The open-access MAF lists 66 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Intron 8, RNA 4, 5'Flank 3, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.539); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCL5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs571565063; called by muse, mutect2, varscan2
- CPOX | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51639671; called by muse, mutect2, varscan2
- DGKI | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs774412671, COSV55936948; called by muse, mutect2, varscan2
- DSC2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs775614779, COSV51862833; called by muse, mutect2, varscan2
- ELAVL3 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1363746056, COSV63645769; called by muse, mutect2, varscan2
- GPR137C | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs556422200; called by muse, mutect2, varscan2
- IL25 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV100198271; called by muse, mutect2, varscan2
- KIF5A | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | catalogued as COSV54056828; called by muse, mutect2, varscan2
- LCT | c.3697G>T p.A1233S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.026); catalogued as rs150342801; called by mutect2, varscan2
- LRIT1 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375680820; called by muse, varscan2
- PPP1R15A | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as COSV99079366; called by muse, mutect2, varscan2
- PUS1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.02); catalogued as rs750562665; called by mutect2, varscan2
- RFX4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV63505971; called by muse, mutect2, varscan2
- TYRO3 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV99778309; called by muse, mutect2
- CUBN | c.2978A>G p.Y993C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DOCK1 | c.5521C>G p.P1841A | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FAM120C | c.2507A>G p.D836G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FASN | c.7214T>G p.I2405S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KMT2C | c.3065T>G p.L1022R | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACC1 | c.1447T>C p.F483L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MCM10 | c.563G>A p.R188K (on ENST00000484800 / NM_182751.3; = p.R187K on NM_018518.5) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MS4A12 | c.384T>G p.I128M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NOL8 | c.769dup p.R257Kfs*4 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- PDE9A | c.863del p.F288Sfs*36 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- PPP1R13B | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS7 | c.313A>C p.T105P | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RUNX2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2
- SCG2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by mutect2, varscan2
- SNRK | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNGAP1 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.193); called by mutect2, varscan2
- TNFRSF21 | c.1060A>C p.I354L | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRHDE | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2
- AC098582.1 | c.1419T>C p.S473= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- CPSF1 | c.2700C>T p.N900= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- DDX11 | c.589C>T p.L197= | Silent (SNP) | VAF 64/270 reads (24%) | called by muse, varscan2
- HSPG2 | c.9549T>C p.Y3183= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs747050010; called by muse, mutect2, varscan2
- KCNK2 | c.387T>C p.I129= (on ENST00000444842 / NM_001017425.3; = p.I114= on NM_014217.4) | Silent (SNP) | VAF 35/57 reads (61%) | called by muse, mutect2, varscan2
- LY9 | c.1302C>T p.S434= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs765576030; called by mutect2, varscan2
- MAPK8IP2 | c.291G>A p.E97= | Silent (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- MYOF | c.99G>A p.K33= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63703420; called by muse, varscan2
- NRL | c.702C>T p.H234= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- PDE3B | c.198C>A p.P66= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- PKD1 | c.4653C>T p.L1551= | Silent (SNP) | VAF 161/285 reads (56%) | catalogued as rs769741858; called by muse, mutect2, varscan2
- SLC12A7 | c.1302C>T p.I434= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs746691377, COSV53760134; called by muse, mutect2, varscan2
- SLC4A5 | c.1575C>A p.I525= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV61030803; called by muse, mutect2, varscan2
- TLN2 | c.6732C>T p.C2244= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- TNPO3 | c.1047G>C p.L349= | Silent (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- VWA8 | c.5094G>C p.R1698= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV65000891; called by muse, mutect2, varscan2
- AC133561.1 | n.1953C>A | RNA (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- ARFGAP3 | chr22:42858434 G>A | 5'Flank (SNP) | VAF 10/109 reads (9%) | catalogued as rs1251867768; called by muse, mutect2
- ASAH1 | c.551+33T>C | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, varscan2
- C12orf57 | chr12:6943202 T>C | 5'Flank (SNP) | VAF 7/30 reads (23%) | called by mutect2, varscan2
- CSPP1 | c.330+553A>C | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- LARS2 | c.*1094C>G | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2
- LINC00303 | n.110C>T | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, varscan2
- MCFD2 | chr2:46917277 G>C | 5'Flank (SNP) | VAF 5/42 reads (12%) | catalogued as rs1368617587, COSV60177774; called by muse, varscan2
- METTL2B | c.*721A>G | 3'UTR (SNP) | VAF 14/110 reads (13%) | catalogued as rs1386784188, COSV52310130; called by muse, varscan2
- MKRN1 | c.186-3272A>G | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as rs1333362392; called by muse, varscan2
- PHC3 | c.379-1400A>G | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- RABGEF1 | c.219-1525G>A | Intron (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs1426585233; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 13/94 reads (14%) | catalogued as rs910081914; called by muse, mutect2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 16/138 reads (12%) | catalogued as rs1554426472; called by muse, mutect2
- TPRXL | n.1110G>T | RNA (SNP) | VAF 30/91 reads (33%) | called by muse, varscan2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs1242378776, COSV54830476; called by muse, varscan2
